Somatic mutation profile of tumor specimen TCGA-BF-A5EO-01A (aliquot TCGA-BF-A5EO-01A-12D-A27K-08) from TCGA case TCGA-BF-A5EO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 65.5 years (23,940 days).
Specimen TCGA-BF-A5EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a4ff3f6-6d5c-48ba-9133-c183757de9c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A5EO-10A (Blood Derived Normal), aliquot TCGA-BF-A5EO-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/208c6aca-f666-4bb2-8f2d-67c375e84c9d

The open-access MAF lists 731 somatic variants for this specimen: 491 protein-altering or splice-affecting, 229 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 448, Silent 229, Nonsense Mutation 27, Splice Site 9, Splice Region 4, Intron 4, RNA 4, Frame Shift Del 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8084C>T p.S2695L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs80359048, CM119496, COSV66456629; ClinVar: likely benign / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.12617G>A p.W4206* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs372118787, COSV54239421; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 121/283 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 121/279 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 32/106 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs397516827, CM073300, COSV52574365, COSV52575478; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- ABCA13 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.149); catalogued as COSV101329955; called by muse, varscan2
- ABCA13 | c.2174T>A p.L725H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.849); catalogued as COSV101329956; called by muse, mutect2, varscan2
- ABCC12 | c.2662G>A p.V888M | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.217); catalogued as COSV100252291; called by muse, mutect2, varscan2
- ABCC8 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765626111, COSV56856749; called by muse, mutect2, varscan2
- ABCG4 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145359289; called by muse, mutect2, varscan2
- ABO | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101505943; called by muse, mutect2, varscan2
- ACKR1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929496; called by muse, mutect2, varscan2
- ADAM2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55867667, COSV55867844; called by muse, mutect2, varscan2
- ADAMDEC1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56474653, COSV99835826; called by muse, mutect2, varscan2
- ADAMTS17 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.977); catalogued as COSV99170409; called by muse, mutect2, varscan2
- ADAMTS8 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.108); catalogued as COSV99960456; called by muse, mutect2, varscan2
- ADCY1 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99811469; called by muse, mutect2, varscan2
- ADCY6 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs747242622, COSV57167802; called by muse, mutect2, varscan2
- ADGRB3 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV65418628; called by muse, mutect2, varscan2
- ADGRL2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99587526; called by muse, mutect2, varscan2
- ADGRL4 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV66062240; called by muse, mutect2, varscan2
- ADGRV1 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67979161; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 141/462 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- AGL | c.3104C>T p.T1035I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV99648679; called by muse, mutect2, varscan2
- AICDA | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs373061990, COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- ALB | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV99890960; called by muse, mutect2, varscan2
- ANK3 | c.5915G>A p.G1972E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99778788; called by muse, mutect2, varscan2
- ANKRD35 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.868); catalogued as rs782294282, COSV62909730; called by muse, mutect2, varscan2
- ANXA6 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100636813; called by muse, mutect2, varscan2
- AP2A2 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs768024984, COSV100172605; called by muse, mutect2, varscan2
- APOB | c.10801C>T p.Q3601* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99264038; called by muse, mutect2, varscan2
- APOB | c.3640C>T p.H1214Y | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99264220; called by muse, mutect2, varscan2
- ARHGAP17 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253017; called by muse, mutect2, varscan2
- ARHGAP18 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100936039; called by muse, mutect2
- ARHGAP39 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99430478; called by muse, mutect2, varscan2
- ARHGEF11 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV63815732; called by muse, mutect2, varscan2
- ARHGEF15 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100730003; called by muse, mutect2, varscan2
- ARID4A | c.3158T>C p.V1053A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV100794090; called by muse, mutect2, varscan2
- ARL6IP5 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99832946; called by muse, mutect2, varscan2
- ASH1L | c.8867G>A p.R2956Q (on ENST00000368346 / NM_001366177.2; = p.R2951Q on NM_018489.3) | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs756414058, COSV64206037; called by muse, mutect2, varscan2
- ASTN2 | c.1930G>A p.D644N (on ENST00000313400 / NM_001365069.1; = p.D593N on NM_014010.5) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV100525369; called by muse, mutect2, varscan2
- ATG2A | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV101033978; called by muse, mutect2, varscan2
- ATG2A | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV101033981; called by muse, mutect2, varscan2
- ATOH1 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100024456; called by muse, mutect2, varscan2
- ATP2C2 | c.1801G>A p.G601R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52296666; called by muse, mutect2, varscan2
- ATXN7 | c.1530T>G p.H510Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV99893943; called by muse, mutect2, varscan2
- B3GALT1 | c.930A>T p.E310D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV100002548; called by muse, mutect2, varscan2
- BANK1 | c.2097G>T p.E699D | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.203); catalogued as COSV59850848; called by muse, mutect2, varscan2
- BCAR3 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs753125244, COSV99550391; called by muse, mutect2, varscan2
- BNC1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV100596970; called by muse, mutect2, varscan2
- BOD1L1 | c.5177C>T p.T1726I | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV50006771, COSV99238656; called by muse, mutect2, varscan2
- BPIFA3 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV100967014, COSV64926493; called by muse, mutect2, varscan2
- BRINP1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV56296860; called by muse, mutect2, varscan2
- BSN | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs767139152, COSV99607579; called by muse, mutect2, varscan2
- BTBD2 | c.1182-1G>A p.X394_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99724592; called by muse, mutect2, varscan2
- C11orf80 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100690788; called by muse, mutect2, varscan2
- C12orf54 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100011527; called by muse, mutect2, varscan2
- C3AR1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV50818743, COSV99368193; called by muse, mutect2, varscan2
- C8B | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV100980714; called by muse, mutect2, varscan2
- CACNA2D3 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 44/153 reads (29%) | catalogued as COSV55522121; called by muse, mutect2, varscan2
- CADPS | c.2026T>G p.F676V | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV99336483; called by muse, mutect2
- CALB2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs867906130, COSV100226115; called by muse, mutect2, varscan2
- CALB2 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100226119; called by muse, mutect2, varscan2
- CAPN3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV100532634; called by muse, mutect2, varscan2
- CARD10 | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99324728; called by muse, mutect2, varscan2
- CCN4 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136988; called by muse, mutect2, varscan2
- CCSER2 | c.1731T>G p.F577L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV99825598; called by muse, mutect2, varscan2
- CD101 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs768942188, COSV99869240; called by muse, mutect2, varscan2
- CD163 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV63136965; called by muse, mutect2, varscan2
- CD163L1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV100549799; called by muse, mutect2, varscan2
- CD8B | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV100514398; called by muse, mutect2, varscan2
- CD96 | c.1720G>A p.E574K (on ENST00000283285 / NM_198196.3; = p.E558K on NM_005816.5) | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201121432, COSV51912523, COSV51916031; called by muse, mutect2, varscan2
- CDCA7 | c.311C>T p.S104F (on ENST00000347703 / NM_145810.3; = p.S183F on NM_031942.5) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60721786; called by muse, mutect2, varscan2
- CDH4 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV100848503; called by muse, mutect2, varscan2
- CDX1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51567881; called by muse, mutect2, varscan2
- CELA1 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99530003; called by mutect2, varscan2
- CENPF | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV65278465; called by muse, mutect2, varscan2
- CENPF | c.5549C>T p.S1850F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV65279230; called by muse, mutect2, varscan2
- CERKL | c.1540G>A p.E514K (on ENST00000339098 / NM_001030311.2; = p.E488K on NM_201548.5) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV59202412; called by muse, mutect2, varscan2
- CES1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV100828589; called by muse, mutect2, varscan2
- CFAP54 | c.5033C>T p.P1678L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV61570995; called by muse, mutect2, varscan2
- CFAP54 | c.6781G>A p.E2261K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100733017; called by muse, mutect2, varscan2
- CFAP57 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100763996; called by muse, mutect2
- CFAP61 | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99843726; called by muse, mutect2, varscan2
- CFAP70 | c.2281C>T p.H761Y | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as rs143013340; called by muse, mutect2, varscan2
- CHGB | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100972932; called by muse, mutect2, varscan2
- CHI3L2 | c.606-1G>A p.X202_splice | Splice Site (SNP) | VAF 78/334 reads (23%) | catalogued as rs1365700593, COSV100869267; called by muse, mutect2, varscan2
- CHST15 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs765822393, COSV100654982; called by muse, mutect2, varscan2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2, varscan2
- CNST | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100829819, COSV104426167; called by muse, mutect2, varscan2
- CNTN4 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100638935; called by muse, mutect2
- CNTRL | c.3889C>A p.P1297T | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV99441439; called by muse, mutect2, varscan2
- COL11A1 | c.4169G>A p.G1390E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62172317; called by muse, mutect2, varscan2
- COL11A2 | c.5029G>T p.E1677* (on ENST00000341947 / NM_080680.3; = p.E1570* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100553568, COSV100554534; called by muse, mutect2, varscan2
- COL19A1 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV100505524; called by muse, mutect2, varscan2
- COL19A1 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100505525; called by muse, mutect2, varscan2
- COL24A1 | c.4343C>T p.P1448L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100993024; called by muse, mutect2, varscan2
- COL28A1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs745883832, COSV101258394; called by muse, mutect2, varscan2
- COL4A1 | c.4483C>T p.R1495C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539786257, COSV101011000; called by muse, mutect2, varscan2
- COL6A3 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs759280111, COSV55093795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99657291; called by muse, varscan2
- COL8A1 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV53732789; called by muse, varscan2
- COL9A3 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100673220; called by muse, mutect2, varscan2
- COP1 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV100442906; called by muse, mutect2, varscan2
- CORO6 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1242132064, COSV100801156; called by muse, mutect2, varscan2
- CRB1 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 51/149 reads (34%) | catalogued as COSV100957725; called by muse, mutect2, varscan2
- CRISP1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV100236682, COSV59994164; called by muse, mutect2, varscan2
- CRLF2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759127718, COSV67493497; called by muse, mutect2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, mutect2, varscan2
- CTNND2 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs141186137, COSV58896895; called by muse, mutect2, varscan2
- CWF19L2 | c.923T>G p.V308G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs758386751, COSV99978506; called by muse, varscan2
- CX3CR1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64194994; called by muse, mutect2, varscan2
- CXCL14 | c.227C>T p.S76F (on ENST00000337225; = p.S64F on NM_004887.5) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100463522; called by muse, mutect2, varscan2
- CYB5R4 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100859641; called by muse, mutect2, varscan2
- CYLC1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100254220, COSV61412423; called by muse, mutect2, varscan2
- CYP2A13 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.118); catalogued as COSV100386671; called by muse, mutect2, varscan2
- CYTIP | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.172); catalogued as rs1213801186, COSV99938659; called by muse, mutect2, varscan2
- DCC | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs759718173, COSV100498675, COSV59118423; called by muse, mutect2, varscan2
- DEFB129 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as COSV99857374; called by muse, mutect2, varscan2
- DHPS | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV99269542; called by muse, mutect2, varscan2
- DKK3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100484941; called by muse, mutect2, varscan2
- DNAH5 | c.975G>A p.K325= | Splice Region (SNP) | VAF 37/147 reads (25%) | catalogued as COSV99446197, COSV99451814; called by muse, mutect2, varscan2
- DNAH7 | c.6358G>A p.D2120N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV56751887; called by muse, mutect2, varscan2
- DNAJC8 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.986); catalogued as COSV55281889, COSV99746092; called by muse, mutect2, varscan2
- DNASE2B | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV101042860, COSV65743349; called by muse, mutect2, varscan2
- DOCK11 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV52239547, COSV99353144; called by muse, mutect2, varscan2
- DOCK9 | c.2977C>T p.H993Y (on ENST00000376460 / NM_001366676.2; = p.H994Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV59620841; called by muse, mutect2, varscan2
- DOK7 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100403190; called by muse, mutect2, varscan2
- DPPA4 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs867198096, COSV59509181; called by muse, mutect2, varscan2
- DSC1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.484); catalogued as rs1287215123, COSV57145286; called by muse, mutect2, varscan2
- DTNBP1 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.526); catalogued as COSV100160475; called by muse, mutect2, varscan2
- DUSP12 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV100909686, COSV63411453; called by muse, mutect2, varscan2
- EDEM1 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56584127, COSV99849064; called by muse, mutect2, varscan2
- EFEMP1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62617821; called by muse, mutect2, varscan2
- EFHB | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.108); catalogued as COSV99859258; called by muse, mutect2, varscan2
- EGFL7 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs200663721, COSV100451913; called by muse, mutect2, varscan2
- EML1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs766326324, COSV99214643; called by muse, mutect2, varscan2
- ENAM | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV68535136; called by muse, mutect2, varscan2
- EP400 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100200662; called by muse, mutect2, varscan2
- EPB41 | c.1522C>T p.R508* (on ENST00000343067 / NM_001166005.2; = p.R299* on NM_004437.4) | Nonsense Mutation (SNP) | VAF 109/226 reads (48%) | catalogued as COSV100548243; called by muse, mutect2, varscan2
- EPHA3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.455); catalogued as rs201357801, COSV60697402, COSV60698509; called by muse, mutect2, varscan2
- EPPK1 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV101599763; called by muse, mutect2, varscan2
- EPPK1 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV73261023; called by muse, mutect2, varscan2
- ERICH3 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV58623166; called by muse, mutect2, varscan2
- EYA4 | c.1076G>A p.G359E (on ENST00000531901 / NM_001301013.1; = p.G353E on NM_004100.5) | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs267600817, COSV62047346; called by muse, mutect2, varscan2
- F5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752636369, COSV63123123; called by muse, mutect2, varscan2
- FAM135B | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs370285922; called by muse, mutect2, varscan2
- FAT3 | c.13408G>A p.E4470K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs753317758, COSV53114577; called by muse, mutect2, varscan2
- FAT4 | c.5509C>A p.H1837N | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV100627575; called by muse, mutect2, varscan2
- FAT4 | c.13456C>T p.P4486S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.053); catalogued as COSV100627579; called by muse, varscan2
- FBXO40 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100572987, COSV57526304; called by muse, mutect2, varscan2
- FCGBP | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1306932095; called by muse, mutect2, varscan2
- FCRL5 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62512252; called by muse, mutect2, varscan2
- FHIT | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs755023954, COSV59285971; called by muse, mutect2, varscan2
- FKBP9 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV99639116; called by muse, mutect2, varscan2
- FLNC | c.6397C>T p.R2133C | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1186464414, COSV100367728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXA3 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145277260; called by muse, mutect2, varscan2
- FPGS | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948779; called by muse, mutect2, varscan2
- FSIP2 | c.18352G>C p.V6118L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100554369; called by muse, mutect2, varscan2
- FUS | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 71/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99568360; called by muse, mutect2, varscan2
- FUT6 | c.625T>A p.Y209N | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54608210, COSV99744344; called by muse, mutect2, varscan2
- GABRB2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs745319567, COSV50952878; called by muse, mutect2, varscan2
- GABRD | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379512215; called by muse, mutect2
- GALE | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs140878602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAPVD1 | c.2926C>T p.P976S (on ENST00000394104; = p.P1003S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.979); catalogued as COSV99782816; called by muse, mutect2, varscan2
- GART | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.234); catalogued as COSV101111356; called by muse, mutect2, varscan2
- GATB | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs865797610, COSV56129546, COSV99858813; called by muse, mutect2, varscan2
- GBP1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100976234; called by muse, mutect2, varscan2
- GCNT3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.489); catalogued as COSV101251737; called by muse, mutect2, varscan2
- GDAP1L1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV61156472; called by muse, mutect2, varscan2
- GGT7 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV60540345; called by muse, mutect2, varscan2
- GLB1L2 | c.734-1G>A p.X245_splice | Splice Site (SNP) | VAF 111/373 reads (30%) | catalogued as COSV100335201; called by muse, mutect2, varscan2
- GNA13 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101457432, COSV71475014; called by muse, mutect2, varscan2
- GOLGB1 | c.9341C>T p.P3114L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100510427; called by muse, mutect2, varscan2
- GOLGB1 | c.9340C>T p.P3114S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1261573112, COSV100510429; called by muse, mutect2, varscan2
- GPX5 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101297247; called by muse, mutect2, varscan2
- GRIN2A | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1555481892, COSV58025645; called by muse, mutect2, varscan2
- GRIN3A | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV100701395; called by muse, mutect2, varscan2
- GRM7 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761983302, COSV63151566; called by muse, mutect2, varscan2
- GRM7 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100735898; called by muse, mutect2, varscan2
- GUCA2B | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV65367945; called by muse, mutect2
- GUCY2F | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV99484646; called by muse, mutect2, varscan2
- HABP2 | c.1430G>C p.C477S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667860, COSV63493263; called by muse, mutect2, varscan2
- HDAC9 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs1329527593, COSV67772207; called by muse, mutect2
- HECW1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.129); catalogued as rs867994249, COSV101222989, COSV101224096; called by muse, mutect2, varscan2
- HOXD8 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.497); catalogued as rs775337191, COSV100497023; called by muse, mutect2, varscan2
- HRH4 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs867641946, COSV99907760; called by muse, mutect2, varscan2
- HRNR | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs201506455, COSV64261722, COSV64262317; called by muse, mutect2, varscan2
- HSD17B14 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV54415483, COSV99622661; called by muse, mutect2, varscan2
- HYDIN | c.12422G>A p.G4141D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124957; called by mutect2, varscan2
- IBTK | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291291436, COSV100090016; called by muse, mutect2, varscan2
- IGKV1-5 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs377210024; called by muse, mutect2, varscan2
- IGSF1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100811920; called by muse, mutect2, varscan2
- IGSF3 | c.2317G>A p.E773K (on ENST00000369486 / NM_001007237.3; = p.E793K on NM_001542.4) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs761730940, COSV59588234; called by muse, mutect2, varscan2
- IL24 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99686397; called by muse, mutect2, varscan2
- IL27 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100112341; called by muse, mutect2, varscan2
- IMPG1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV100886191; called by muse, mutect2, varscan2
- IMPG1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as COSV100886195; called by muse, mutect2, varscan2
- IQSEC3 | c.1043C>A p.P348Q (on ENST00000538872 / NM_001170738.2; = p.P45Q on NM_015232.1) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100406922; called by muse, mutect2, varscan2
- IREB2 | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772091594, COSV51920695; called by muse, mutect2, varscan2
- IRF2BP1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1416861907, COSV100138820; called by muse, mutect2, varscan2
- ITGA6 | c.1490C>T p.S497L (on ENST00000442250; = p.S458L on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV99905207; called by muse, mutect2, varscan2
- ITGAE | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV99560374, COSV99560535; called by muse, mutect2, varscan2
- ITIH4 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1482132118, COSV56573352, COSV99819002; called by muse, mutect2, varscan2
- KAZN | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.049); catalogued as rs1257675758, COSV100747698; called by muse, mutect2, varscan2
- KCNB2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as rs200347487, COSV73051536; called by muse, mutect2, varscan2
- KCNH6 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 252/406 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs760547462, COSV100120862; called by muse, mutect2, varscan2
- KCNQ5 | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1156363948, COSV100571539, COSV59674664; called by muse, mutect2, varscan2
- KCNU1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369264156; called by muse, mutect2, varscan2
- KDM5A | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV66990474, COSV66994298; called by muse, mutect2, varscan2
- KDR | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV55763194; called by muse, mutect2, varscan2
- KIAA1549L | c.1867C>T p.P623S (on ENST00000321505; = p.P920S on NM_012194.3) | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.131); catalogued as rs1035837354, COSV99682840; called by muse, mutect2, varscan2
- KIF21B | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100143968; called by muse, mutect2, varscan2
- KLHDC7A | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 86/164 reads (52%) | catalogued as rs773474677, COSV68769112; called by muse, mutect2, varscan2
- KLKB1 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs867707828, COSV52995896; called by muse, mutect2, varscan2
- KMT2C | c.916T>G p.Y306D | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100068701; called by muse, mutect2, varscan2
- KPRP | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100908675; called by muse, mutect2
- KRBA1 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99752308; called by muse, mutect2, varscan2
- L1CAM | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 102/183 reads (56%) | catalogued as COSV100648911; called by muse, mutect2, varscan2
- LGR6 | c.890G>T p.G297V (on ENST00000367278 / NM_001017403.1; = p.G245V on NM_021636.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55159343, COSV99706300; called by muse, mutect2, varscan2
- LHCGR | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54295272, COSV99683313; called by muse, mutect2, varscan2
- LILRB2 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100079104; called by muse, varscan2
- LIPH | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 41/152 reads (27%) | catalogued as COSV99955827; called by muse, mutect2, varscan2
- LMAN2L | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.456); catalogued as COSV99383172; called by muse, mutect2, varscan2
- LMO7 | c.4646C>T p.S1549F (on ENST00000357063; = p.S1230F on NM_005358.5) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100412651; called by muse, mutect2, varscan2
- LPAR1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as rs778764227, COSV100730754; called by muse, mutect2, varscan2
- LPCAT4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406096238, COSV59217074; called by muse, mutect2, varscan2
- LRCH4 | c.667T>A p.F223I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100052749; called by muse, mutect2, varscan2
- LRP2 | c.11201C>T p.P3734L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293781540, COSV55581217; called by muse, mutect2, varscan2
- LRP2 | c.7340C>T p.S2447F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV55548866; called by muse, mutect2, varscan2
- LRRC24 | c.612C>G p.N204K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748390301, COSV99467184; called by muse, mutect2, varscan2
- LTBP2 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.419); catalogued as rs61738014, COSV56214210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LTBP4 | c.4525T>A p.F1509I (on ENST00000308370 / NM_001042544.1; = p.F1472I on NM_003573.2) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99181131; called by muse, mutect2, varscan2
- LUZP1 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 37/194 reads (19%) | catalogued as COSV100034622; called by muse, mutect2, varscan2
- MACF1 | c.21779C>T p.P7260L (on ENST00000372915; = p.P5305L on NM_012090.5) | Missense Mutation (SNP) | VAF 100/234 reads (43%) | catalogued as rs748487650, COSV99242173; called by muse, mutect2, varscan2
- MAN2C1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV99145264; called by muse, mutect2, varscan2
- MAP3K10 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99454095; called by muse, mutect2, varscan2
- MCTP1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV56529629; called by muse, mutect2, varscan2
- MDGA2 | c.2446C>T p.H816Y (on ENST00000399232 / NM_001113498.2; = p.H518Y on NM_182830.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.844); catalogued as COSV100636525, COSV62091648; called by muse, mutect2, varscan2
- MDGA2 | c.2380G>A p.E794K (on ENST00000399232 / NM_001113498.2; = p.E496K on NM_182830.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.759); catalogued as COSV100636526; called by muse, mutect2, varscan2
- MDH1B | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100982149; called by muse, mutect2, varscan2
- MECOM | c.3074C>T p.S1025F (on ENST00000468789 / NM_001105078.4; = p.S1213F on NM_004991.4) | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52960428; called by muse, mutect2, varscan2
- MED13L | c.6223C>T p.R2075W | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56121780, COSV99928089; called by muse, mutect2, varscan2
- MED14 | c.240A>G p.E80= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100247378; called by muse, mutect2
- MED23 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV100644820; called by muse, mutect2, varscan2
- MET | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100577068; called by muse, mutect2, varscan2
- MFSD4A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100901463; called by muse, mutect2, varscan2
- MIA3 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1001565873, COSV60514248; called by muse, mutect2, varscan2
- MICALL2 | c.1982C>A p.P661Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as COSV99875722; called by muse, mutect2, varscan2
- MKRN3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs777359232, COSV58810220; called by muse, mutect2, varscan2
- MLH3 | c.1765A>G p.N589D | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99469780; called by muse, mutect2, varscan2
- MMS22L | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99246286; called by muse, mutect2, varscan2
- MMS22L | c.999C>A p.D333E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV51524744; called by muse, mutect2, varscan2
- MNDA | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV63740172; called by muse, mutect2, varscan2
- MORN3 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100804446, COSV62507144; called by muse, mutect2, varscan2
- MRM2 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99642588; called by muse, mutect2, varscan2
- MROH7 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as rs756790243, COSV100273106; called by muse, mutect2, varscan2
- MTHFD2L | c.806-1G>A p.X269_splice (on ENST00000395759 / NM_001144978.2; = p.X211_splice on NM_001004346.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 41/142 reads (29%) | catalogued as COSV57469987; called by muse, mutect2, varscan2
- MTTP | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV99644850; called by muse, mutect2, varscan2
- MUC16 | c.37219C>T p.H12407Y | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.149); catalogued as COSV101198672; called by muse, mutect2, varscan2
- MUC16 | c.25364C>T p.S8455F | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs974498166, COSV101198673; called by muse, mutect2, varscan2
- MUC3A | c.7997G>A p.G2666E | Missense Mutation (SNP) | VAF 112/801 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.537); catalogued as rs762464654, COSV60211557; called by muse, mutect2, varscan2
- MUC5B | c.12284G>A p.R4095K | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV101500094; called by muse, mutect2, varscan2
- MYO7A | c.6220C>T p.P2074S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as rs747131589, CM140461, COSV101289069; ClinVar: uncertain significance; called by muse, varscan2
- N4BP1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.212); catalogued as COSV52213513; called by muse, mutect2, varscan2
- NAALAD2 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs1235539203, COSV100428138; called by muse, mutect2, varscan2
- NEFH | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs1269358882, COSV100151333; called by muse, varscan2
- NEK10 | c.1750C>T p.H584Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100411520; called by muse, mutect2, varscan2
- NELFE | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs745855032, COSV100952645; called by muse, mutect2, varscan2
- NES | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 100/387 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV100957784; called by muse, mutect2, varscan2
- NFIC | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100545118; called by muse, mutect2, varscan2
- NLGN4Y | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100196357; called by muse, mutect2, varscan2
- NLRP9 | c.2701T>G p.C901G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV100242713; called by muse, mutect2, varscan2
- NOD1 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs148340769; called by muse, mutect2, varscan2
- NOMO1 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 62/566 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1274625131, COSV99814274; called by muse, mutect2, varscan2
- NPAS3 | c.914C>T p.P305L (on ENST00000356141 / NM_001164749.2; = p.P273L on NM_022123.3) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV100639833; called by muse, mutect2, varscan2
- NPTN | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.055); catalogued as COSV99766329; called by muse, mutect2, varscan2
- NUFIP2 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1371559323, COSV99837273; called by muse, mutect2, varscan2
- NXPE4 | c.1130G>A p.G377E (on ENST00000375478 / NM_001077639.2; = p.G93E on NM_017678.3) | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs945992162, COSV64943396; called by muse, mutect2, varscan2
- OGDHL | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100934219; called by muse, mutect2, varscan2
- ONECUT2 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs954601926, COSV72152977; called by muse, mutect2, varscan2
- OPRD1 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99330121; called by muse, mutect2, varscan2
- OR10A6 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV100564248; called by muse, mutect2, varscan2
- OR11H12 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1359990652, COSV73569310; called by muse, varscan2
- OR13C5 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101053037; called by muse, mutect2, varscan2
- OR1A2 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as COSV101126341; called by muse, mutect2
- OR1N2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV101031354; called by muse, mutect2
- OR2F1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.672); catalogued as rs1450373104, COSV101231293; called by muse, mutect2, varscan2
- OR2M5 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100822884, COSV63545815; called by muse, mutect2, varscan2
- OR2T2 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs761691021, COSV100737592; called by muse, mutect2, varscan2
- OR4D10 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101597000; called by muse, mutect2, varscan2
- OR4M1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.367); catalogued as rs201377742, COSV100270969, COSV60060509; called by muse, varscan2
- OR51A7 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100834604; called by muse, mutect2, varscan2
- OR52N4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.065); catalogued as rs753488958, COSV100421596; called by muse, mutect2, varscan2
- OR5AS1 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100546191, COSV57983467; called by muse, mutect2, varscan2
- OR5H1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV100641594; called by muse, mutect2, varscan2
- OR9A4 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV101516362; called by muse, mutect2, varscan2
- OSBP2 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs766186671, COSV100212746; called by muse, mutect2, varscan2
- OTOF | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV99716846; called by muse, mutect2, varscan2
- OTUD7B | c.1420A>C p.S474R | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100967408; called by muse, mutect2, varscan2
- PAK4 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV100426397; called by muse, mutect2, varscan2
- PALLD | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs748036704, COSV99824091; called by muse, mutect2, varscan2
- PBXIP1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100870023; called by muse, mutect2, varscan2
- PCLO | c.12050A>T p.E4017V | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100428667; called by muse, mutect2, varscan2
- PCLO | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs757147395, COSV100428668; called by muse, mutect2, varscan2
- PDE4DIP | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100517385; called by muse, mutect2, varscan2
- PDGFD | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100158205; called by muse, mutect2, varscan2
- PDZD8 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100559436; called by muse, mutect2, varscan2
- PGBD1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as COSV99459851; called by muse, mutect2, varscan2
- PGK2 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 46/203 reads (23%) | catalogued as rs771269272, COSV100505365; called by muse, mutect2, varscan2
- PGLYRP4 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); catalogued as rs1320592409, COSV100668328; called by muse, mutect2, varscan2
- PGS1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.505); catalogued as COSV99428087; called by muse, mutect2, varscan2
- PIK3AP1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs781711324, COSV59534877; called by muse, mutect2, varscan2
- PIK3C2A | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99790367; called by muse, mutect2, varscan2
- PIK3C2G | c.2791G>A p.D931N (on ENST00000676171; = p.D890N on NM_004570.5) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs181773550; called by muse, mutect2, varscan2
- PKD1 | c.3766C>T p.P1256S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs745647957, COSV99237406; called by muse, mutect2, varscan2
- PKP2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99297362; called by muse, mutect2, varscan2
- PLAGL1 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV52788871; called by muse, mutect2, varscan2
- PLCH2 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs778497311, COSV99615716; called by muse, mutect2, varscan2
- PLXND1 | c.5695C>T p.R1899W | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs768565508, COSV60712013; called by muse, mutect2, varscan2
- PODXL2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); catalogued as COSV100686198; called by muse, mutect2, varscan2
- POTEF | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.81); catalogued as rs527763469, COSV100664670; called by muse, mutect2, varscan2
- PPP2R2A | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs757712148, COSV60099594; called by muse, mutect2, varscan2
- PRDM12 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs779851108, COSV53392243; called by muse, mutect2, varscan2
- PRKAA2 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs777124193, COSV100982764, COSV64803308; called by muse, mutect2, varscan2
- PROC | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99300693; called by muse, mutect2, varscan2
- PROSER1 | c.2726C>T p.S909L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs974740495, COSV100612691; called by muse, mutect2, varscan2
- PRRC2A | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV101051045; called by muse, mutect2, varscan2
- PRSS16 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100041586; called by muse, mutect2, varscan2
- PSG3 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 158/390 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100548738; called by muse, mutect2, varscan2
- PSKH1 | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99344520; called by muse, mutect2, varscan2
- PSMF1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as rs773972864, COSV99850350; called by muse, mutect2, varscan2
- PSORS1C1 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV99456008; called by muse, mutect2, varscan2
- PTGES2 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as COSV99476261; called by muse, mutect2, varscan2
- PTPRC | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as rs724159905, COSV61412886; called by muse, mutect2, varscan2
- PTPRD | c.3365G>A p.G1122D | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100643816; called by muse, mutect2, varscan2
- PTPRN2 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67039304; called by muse, mutect2, varscan2
- PWWP3B | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV100531019; called by muse, mutect2, varscan2
- RABGGTA | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs369745480; called by muse, mutect2, varscan2
- RALYL | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV72817675; called by muse, mutect2
- RANBP3 | c.1475C>T p.A492V (on ENST00000340578 / NM_007322.3; = p.A487V on NM_003624.3) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99222192; called by muse, mutect2, varscan2
- RASGRP1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1279324286, COSV100171810, COSV60366402; called by muse, mutect2, varscan2
- RASGRP1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as rs768175330, COSV100171811; called by muse, mutect2, varscan2
- RBMXL1 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV99555704; called by muse, mutect2, varscan2
- RD3 | c.294C>T p.L98= | Splice Region (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100879197; called by muse, mutect2, varscan2
- RELB | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.503); catalogued as COSV99672686; called by muse, mutect2, varscan2
- RERG | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV57003638; called by muse, mutect2, varscan2
- REV3L | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100724995; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RPL5 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs764649729, COSV59873485; called by muse, mutect2, varscan2
- RTCB | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.196); catalogued as COSV99321977; called by muse, mutect2, varscan2
- RUFY4 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV100722968; called by mutect2, varscan2
- SALL1 | c.3904A>G p.S1302G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99171792; called by muse, mutect2, varscan2
- SALL4 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs771797918, COSV99409274; called by muse, mutect2, varscan2
- SAMD7 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs140876134; called by muse, mutect2, varscan2
- SAMD9 | c.3188G>A p.G1063E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV66075340; called by muse, mutect2, varscan2
- SCAPER | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749519165, COSV57758584; called by muse, varscan2
- SCN10A | c.4286G>A p.G1429E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV101479280; called by muse, mutect2, varscan2
- SCN1A | c.5657G>A p.R1886Q (on ENST00000303395 / NM_001202435.3; = p.R1875Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1559100385, CD031887, CM134117, COSV57665487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE1 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs762729489, COSV100682977; called by muse, mutect2, varscan2
- SDK1 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs866176386, COSV101268876; called by muse, mutect2, varscan2
- SEC23B | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99357489; called by muse, mutect2, varscan2
- SEL1L2 | c.1060A>T p.N354Y | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99532766; called by muse, mutect2, varscan2
- SEMA5A | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs530052137, COSV101227370; called by muse, mutect2, varscan2
- SENP7 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV58612013; called by muse, mutect2, varscan2
- SETBP1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.509); catalogued as rs1244101361, COSV99952343; called by muse, mutect2, varscan2
- SFTPD | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100954488; called by muse, mutect2, varscan2
- SH3RF1 | c.1609G>A p.G537R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99498769; called by muse, mutect2, varscan2
- SHANK2 | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV99572697; called by muse, mutect2, varscan2
- SHROOM3 | c.3556G>A p.G1186R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs1483583729, COSV99933759; called by muse, mutect2
- SIGLEC10 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372246670; called by muse, mutect2, varscan2
- SIGLEC11 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV101389134; called by muse, mutect2, varscan2
- SKIL | c.1684T>G p.L562V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.471); catalogued as COSV99378121; called by muse, mutect2
- SLC14A2 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as COSV54910327, COSV99675194; called by muse, mutect2, varscan2
- SLC16A14 | c.143T>G p.M48R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99725295; called by muse, mutect2, varscan2
- SLC22A12 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327442, COSV60573100; called by muse, mutect2
- SLC26A5 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100098810; called by muse, mutect2, varscan2
- SLC2A11 | c.200G>A p.W67* (on ENST00000345044 / NM_001024938.4; = p.W74* on NM_030807.5) | Nonsense Mutation (SNP) | VAF 27/129 reads (21%) | catalogued as COSV99741242; called by muse, mutect2, varscan2
- SLC2A5 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101072627; called by muse, mutect2, varscan2
- SLC2A9 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.808); catalogued as COSV53330977; called by muse, mutect2, varscan2
- SLC39A10 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1156860399, COSV100660495; called by muse, mutect2, varscan2
- SLC39A8 | c.1179T>A p.N393K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100765662; called by muse, mutect2, varscan2
- SLC4A3 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV99812555; called by muse, mutect2, varscan2
- SLC4A5 | c.2319+1G>A p.X773_splice | Splice Site (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100697489; called by muse, mutect2, varscan2
- SLC6A2 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99573469; called by muse, mutect2, varscan2
- SLC9A2 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99295968; called by muse, mutect2, varscan2
- SLC9A4 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs764680635, COSV99762792; called by muse, mutect2, varscan2
- SLFN12 | c.471T>A p.Y157* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100512952; called by muse, mutect2, varscan2
- SLX4 | c.4523C>T p.S1508L | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs112694849, COSV53561934; called by muse, mutect2, varscan2
- SMU1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101238507; called by muse, mutect2, varscan2
- SND1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100689905; called by muse, mutect2, varscan2
- SOGA1 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99413089; called by muse, mutect2, varscan2
- SPAG16 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.877); catalogued as COSV59120849, COSV59126175; called by muse, mutect2, varscan2
- SPAG9 | c.1828C>T p.L610F (on ENST00000262013 / NM_001130528.3; = p.L596F on NM_003971.6) | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV100004689; called by muse, mutect2, varscan2
- SPAM1 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99772789; called by muse, mutect2, varscan2
- SPEF2 | c.5395C>T p.L1799F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.445); catalogued as COSV100288803; called by muse, mutect2, varscan2
- SPG11 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.107); catalogued as COSV56000218; called by muse, mutect2, varscan2
- SPHKAP | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778045595, COSV60870233; called by muse, mutect2, varscan2
- SPHKAP | c.139-1G>A p.X47_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100763806; called by muse, mutect2, varscan2
- SPOP | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100753224; called by muse, mutect2, varscan2
- SPTBN4 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.878); catalogued as rs572155600, COSV100150235; called by muse, mutect2, varscan2
- SREBF2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100761356; called by muse, mutect2
- SRSF8 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101475788; called by muse, mutect2, varscan2
- ST18 | c.2683C>T p.L895F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV52499149; called by muse, mutect2, varscan2
- STAT4 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.607); catalogued as rs267599129, COSV100635987; called by muse, mutect2, varscan2
- STK4 | c.1308T>A p.L436= | Splice Region (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100859966; called by muse, mutect2, varscan2
- STOML3 | c.312+1G>A p.X104_splice | Splice Site (SNP) | VAF 34/129 reads (26%) | catalogued as rs776422641, COSV101105211; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59139287; called by muse, mutect2, varscan2
- STOX2 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100408482; called by muse, mutect2, varscan2
- STXBP5L | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99872572; called by muse, mutect2, varscan2
- STYXL2 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775602117, COSV99608738; called by muse, mutect2, varscan2
- SUPT6H | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.25); catalogued as COSV58925208; called by muse, mutect2, varscan2
- SWT1 | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100833130; called by muse, mutect2, varscan2
- SYCP2L | c.1012-1G>A p.X338_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV51655529, COSV99304820; called by muse, mutect2, varscan2
- SYNE1 | c.8032G>A p.E2678K (on ENST00000367255 / NM_182961.4; = p.E2685K on NM_033071.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99556195; called by muse, mutect2, varscan2
- SYNJ1 | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs757637208, COSV100449051; called by muse, mutect2, varscan2
- TAS1R3 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs951127451, COSV100229323; called by muse, mutect2, varscan2
- TBC1D2B | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs767726812, COSV100316938; called by muse, varscan2
- TCAF2 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV100633548; called by muse, mutect2, varscan2
- TDRKH | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as rs749386396, COSV58618656; called by muse, mutect2, varscan2
- TECTA | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.904); catalogued as rs369100736, COSV99879013; called by muse, mutect2, varscan2
- TECTB | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV101027646, COSV65595057; called by muse, mutect2, varscan2
- TET1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65386448, COSV65390563, COSV65390576; called by muse, mutect2, varscan2
- TGM5 | c.808T>C p.C270R (on ENST00000220420 / NM_201631.4; = p.C188R on NM_004245.4) | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV99588772; called by muse, mutect2, varscan2
- THEMIS | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV64071229; called by muse, mutect2, varscan2
- TNFRSF21 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99729259; called by muse, mutect2, varscan2
- TNXB | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs746282620, COSV100926012; called by muse, mutect2, varscan2
- TRAV13-1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs767404307; called by muse, mutect2, varscan2
- TRBV4-2 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs368250817; called by muse, mutect2, varscan2
- TREH | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs1555144909, COSV99874254; called by muse, mutect2, varscan2
- TRIOBP | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV100730612; called by muse, mutect2, varscan2
- TRPM2 | c.3002C>T p.T1001I | Missense Mutation (SNP) | VAF 120/436 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs143286660; called by muse, mutect2, varscan2
- TRPV6 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100844172, COSV63890236; called by muse, mutect2, varscan2
- TTBK1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52488287; called by muse, mutect2, varscan2
- TTLL12 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776325002, COSV99333256, COSV99333813; called by muse, mutect2, varscan2
- TTLL7 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs995284827, COSV53087608; called by muse, mutect2, varscan2
- TTN | c.68005C>T p.P22669S (on ENST00000591111; = p.P15245S on NM_003319.4) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | PolyPhen benign (0); catalogued as rs987191285, COSV100599390; called by muse, mutect2, varscan2
- TTN | c.47875G>A p.E15959K (on ENST00000591111; = p.E8535K on NM_003319.4) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | PolyPhen benign (0.359); catalogued as rs745629273, COSV59970551; called by muse, mutect2, varscan2
- TTN | c.42358C>T p.P14120S (on ENST00000591111; = p.P6696S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | PolyPhen benign (0.436); catalogued as rs766763223, COSV100599395; called by muse, mutect2, varscan2
- TTN | c.34969C>T p.P11657S (on ENST00000591111; = p.P10730S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | PolyPhen probably damaging (0.998); catalogued as COSV100599398; called by muse, mutect2, varscan2
- TTN | c.25649G>A p.G8550E (on ENST00000591111; = p.G7623E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | PolyPhen possibly damaging (0.676); catalogued as rs369142169; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.22531T>G p.W7511G (on ENST00000591111; = p.W6584G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV100599403; called by muse, mutect2, varscan2
- TTN | c.12890A>T p.D4297V (on ENST00000591111; = p.D4251V on NM_003319.4) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100599405; called by muse, mutect2, varscan2
- TUBB1 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV99413955; called by muse, mutect2, varscan2
- TULP4 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs922168133, COSV100893245; called by muse, mutect2, varscan2
- TYK2 | c.2614C>T p.H872Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99314401; called by muse, mutect2, varscan2
- UBE3B | c.2545T>A p.Y849N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); catalogued as COSV100688567; called by muse, mutect2, varscan2
- UBQLN3 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV100293417, COSV100293425; called by muse, mutect2, varscan2
- UBR4 | c.1709A>G p.Y570C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100920521; called by muse, mutect2, varscan2
- UGT2A1 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV99683979; called by muse, mutect2, varscan2
- UGT2B10 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750785268, COSV99607973; called by muse, mutect2, varscan2
- UGT2B17 | c.656T>A p.L219H | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs779647265, COSV100497178; called by muse, mutect2, varscan2
- URAD | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV100229536; called by muse, mutect2, varscan2
- USH2A | c.15519+1G>A p.X5173_splice | Splice Site (SNP) | VAF 26/84 reads (31%) | catalogued as COSV100230833; called by muse, mutect2, varscan2
- USH2A | c.9529G>A p.E3177K | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100230839; called by muse, mutect2, varscan2
- USP42 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100084059; called by muse, mutect2, varscan2
- VEGFC | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.87); catalogued as rs1364446269, COSV54593527, COSV54596932; called by muse, mutect2, varscan2
- VNN2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58472385, COSV58474998; called by muse, mutect2, varscan2
- VPS13B | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100661097; called by muse, mutect2, varscan2
- WDR33 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.276); catalogued as COSV100459696; called by muse, mutect2, varscan2
- WDR41 | c.205T>G p.W69G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99689109; called by muse, mutect2, varscan2
- WRN | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs199644081, COSV53295673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.616G>T p.D206Y (on ENST00000628543; = p.D381Y on NM_152381.6) | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54693031, COSV99739645; called by muse, mutect2, varscan2
- ZFAT | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100914323; called by muse, mutect2, varscan2
- ZFHX4 | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1338658046, COSV50667561, COSV99029676; called by muse, mutect2, varscan2
- ZNF17 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs369075591; called by muse, mutect2, varscan2
- ZNF197 | c.2270C>T p.T757I | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100482017; called by muse, mutect2, varscan2
- ZNF226 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1274641249, COSV100335046; called by muse, mutect2, varscan2
- ZNF330 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as COSV99522441; called by muse, mutect2, varscan2
- ZNF37A | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 46/108 reads (43%) | catalogued as COSV100697295; called by muse, mutect2, varscan2
- ZNF536 | c.3712C>T p.L1238F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV62835150; called by muse, mutect2, varscan2
- ZNF555 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV100514553; called by muse, mutect2, varscan2
- ZNF578 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs779932364, COSV101405020; called by muse, mutect2, varscan2
- ZNF592 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100245728, COSV55439286; called by muse, mutect2, varscan2
- ZNF662 | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100066092; called by muse, mutect2, varscan2
- ZNF665 | c.655C>T p.H219Y (on ENST00000600412; = p.H284Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs772661261, COSV101128009; called by muse, mutect2, varscan2
- ZNF705A | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100828278; called by muse, mutect2, varscan2
- ZNF800 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV99757736; called by muse, mutect2, varscan2
- ZNF831 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64043709; called by muse, mutect2
- ZNF831 | c.3866A>G p.N1289S | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100925859; called by muse, mutect2, varscan2
- ZNF835 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs760238869, COSV73379264; called by muse, mutect2, varscan2
- CLEC18B | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.673); called by muse, mutect2
- MUC2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 94/316 reads (30%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- NBPF11 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OR2T35 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by mutect2, varscan2
- PRAMEF15 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 109/568 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRC2A | c.3070del p.R1024Gfs*186 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SGK1 | c.672del p.K224Nfs*7 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- SPINK5 | c.765_778del p.N256Vfs*3 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- AACS | c.1218G>A p.T406= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs147156760; called by muse, mutect2, varscan2
- ABCA7 | c.5520G>C p.V1840= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99565323; called by muse, mutect2, varscan2
- ABCA8 | c.3813C>T p.F1271= | Silent (SNP) | VAF 63/106 reads (59%) | catalogued as COSV99285101; called by muse, mutect2, varscan2
- ADAM21 | c.1548G>A p.E516= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV50789473, COSV99960652; called by muse, mutect2, varscan2
- ADAM33 | c.477G>A p.K159= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as COSV100597732, COSV62935141; called by muse, mutect2, varscan2
- ADAMTS12 | c.3501G>A p.E1167= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV100710426; called by muse, mutect2, varscan2
- ADAMTS3 | c.2463A>G p.T821= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs1420517316, COSV99710437; called by muse, mutect2, varscan2
- ADCK5 | c.742C>T p.L248= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs782121915, COSV100450269; called by muse, mutect2, varscan2
- ADCY8 | c.2391C>T p.F797= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs267601771, COSV53897529, COSV99654296; called by muse, mutect2, varscan2
- AFDN | c.2139G>A p.L713= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100652633; called by muse, mutect2, varscan2
- AKAP12 | c.3051G>A p.E1017= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99482712; called by muse, mutect2, varscan2
- AKR1C2 | c.720C>T p.V240= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV101060403; called by mutect2, varscan2
- AKR1C3 | c.720C>T p.V240= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs544284218, COSV101003034; called by muse, mutect2, varscan2
- ALK | c.2320C>T p.L774= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV66561100, COSV66564098; called by muse, mutect2, varscan2
- ANKRD30A | c.3363G>A p.L1121= (on ENST00000611781; = p.L1065= on NM_052997.2) | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV64612112; called by muse, mutect2, varscan2
- ASXL2 | c.2355C>T p.V785= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV99710461; called by muse, mutect2, varscan2
- B3GNT3 | c.129C>T p.I43= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100592655; called by muse, mutect2, varscan2
- BCL2L14 | c.714G>A p.Q238= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs765787822, COSV99844910; called by muse, mutect2, varscan2
- BMP2 | c.378G>A p.G126= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs904725474, COSV66579396; called by muse, mutect2, varscan2
- BNIPL | c.648C>T p.I216= | Silent (SNP) | VAF 119/390 reads (31%) | catalogued as COSV99764557; called by muse, mutect2, varscan2
- BSN | c.7593C>T p.L2531= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99607581; called by muse, mutect2, varscan2
- C20orf194 | c.1242G>A p.L414= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs1174970837, COSV99330384; called by muse, mutect2, varscan2
- C7 | c.2442G>A p.T814= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs374829582; called by muse, mutect2, varscan2
- CACNA1B | c.1959C>T p.I653= | Silent (SNP) | VAF 90/349 reads (26%) | catalogued as COSV99495752; called by muse, mutect2, varscan2
- CAPN15 | c.2160C>T p.S720= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as COSV99562257; called by muse, mutect2, varscan2
- CATSPERD | c.216T>C p.F72= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs1289187995, COSV101062436; called by muse, mutect2, varscan2
- CCDC191 | c.735G>A p.E245= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as COSV99877995; called by muse, mutect2, varscan2
- CDCA7 | c.1014G>A p.R338= (on ENST00000347703 / NM_145810.3; = p.R417= on NM_031942.5) | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV100143380; called by muse, mutect2, varscan2
- CEACAM16 | c.1251G>A p.V417= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV101312654; called by muse, mutect2, varscan2
- CELA1 | c.627C>T p.P209= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV99530005; called by mutect2, varscan2
- CFAP53 | c.828G>A p.K276= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as COSV101274962; called by muse, mutect2, varscan2
- CFTR | c.600C>T p.F200= | Silent (SNP) | VAF 95/301 reads (32%) | catalogued as rs753492211, COSV50040466; called by muse, mutect2, varscan2
- CHODL | c.279G>A p.G93= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as rs767759893, COSV54733564; called by muse, mutect2, varscan2
- CILP2 | c.2181C>T p.F727= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV52278628; called by muse, mutect2, varscan2
- CKAP2L | c.2007C>T p.I669= | Silent (SNP) | VAF 98/373 reads (26%) | catalogued as COSV100198501; called by muse, mutect2, varscan2
- CLCC1 | c.664C>T p.L222= (on ENST00000356970 / NM_001377464.1; = p.L172= on NM_015127.5) | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as rs1198329648, COSV100206291; called by muse, mutect2, varscan2
- CLEC4E | c.114C>T p.F38= | Silent (SNP) | VAF 105/411 reads (26%) | catalogued as COSV100222544; called by muse, mutect2, varscan2
- CNGA1 | c.1674G>A p.T558= | Silent (SNP) | VAF 55/207 reads (27%) | catalogued as rs1180507153, COSV100652163; called by muse, mutect2, varscan2
- CNGB1 | c.3618G>A p.G1206= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs760012294, COSV99201971; called by muse, mutect2, varscan2
- CNGB1 | c.1323G>A p.A441= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1340175211, COSV99201981; called by muse, mutect2, varscan2
- COL11A2 | c.5028G>A p.P1676= (on ENST00000341947 / NM_080680.3; = p.P1569= on NM_080679.2) | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs144290562; called by muse, mutect2, varscan2
- COL2A1 | c.831C>T p.F277= | Silent (SNP) | VAF 91/323 reads (28%) | catalogued as rs1426770511, COSV100475419, COSV61535352; called by muse, mutect2, varscan2
- COQ4 | c.657C>T p.I219= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100306649; called by muse, mutect2, varscan2
- CPA5 | c.696C>T p.I232= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100812251; called by muse, mutect2, varscan2
- CSMD1 | c.1167C>T p.T389= (on ENST00000520002; = p.T388= on NM_033225.6) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101216310; called by muse, varscan2
- DAZAP1 | c.1188C>T p.N396= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs749676213, COSV99245060; called by muse, mutect2, varscan2
- DCAF17 | c.915C>T p.I305= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs146745875; called by muse, mutect2, varscan2
- DCTN1 | c.1251C>T p.S417= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs1553465163, COSV100720882; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH11 | c.11412G>A p.L3804= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV100177877; called by muse, mutect2, varscan2
- DNAH3 | c.4746C>T p.I1582= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs764245516, COSV54522032; called by muse, mutect2, varscan2
- DNAH8 | c.13161G>A p.K4387= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as rs773105785, COSV59480004; called by muse, mutect2, varscan2
- DSCAM | c.327G>A p.G109= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV68638075; called by muse, mutect2, varscan2
- DSG1 | c.2397C>T p.I799= | Silent (SNP) | VAF 52/171 reads (30%) | catalogued as rs866528031, COSV57133899; called by muse, mutect2, varscan2
- DTNB | c.738C>T p.C246= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99976878; called by muse, mutect2
- DUSP19 | c.579C>T p.F193= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100700206; called by muse, mutect2, varscan2
- DYSF | c.1278G>A p.G426= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99245061; called by muse, mutect2, varscan2
- EGFR | c.639C>T p.I213= | Silent (SNP) | VAF 135/493 reads (27%) | catalogued as COSV51844520, COSV99287865; called by muse, mutect2, varscan2
- ELAPOR2 | c.2946C>T p.I982= (on ENST00000450689 / NM_001142749.3; = p.I815= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99788334; called by muse, mutect2, varscan2
- EMC7 | c.639C>T p.F213= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV99854757; called by muse, mutect2, varscan2
- EMP2 | c.426C>T p.S142= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as rs780335790, COSV100852776; called by muse, mutect2, varscan2
- ENAH | c.1113C>T p.P371= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99490216; called by muse, mutect2, varscan2
- ENTPD2 | c.462C>T p.F154= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1294988452, COSV100445670; called by muse, mutect2, varscan2
- EXPH5 | c.1491G>A p.R497= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99761139; called by muse, mutect2, varscan2
- FAM120A | c.2571C>T p.F857= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1366005266, COSV99464755; called by muse, mutect2, varscan2
- FAM135B | c.765C>T p.L255= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99420500; called by muse, mutect2, varscan2
- FAM3B | c.489G>A p.L163= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100783720; called by muse, mutect2, varscan2
- FASTKD5 | c.474C>T p.L158= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs768935935, COSV99417537; called by muse, mutect2, varscan2
- FAT3 | c.12015C>T p.F4005= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1462203233, COSV53103940; called by muse, mutect2, varscan2
- FAT4 | c.13434G>A p.G4478= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as COSV100627576, COSV58686233; called by muse, varscan2
- FCHSD2 | c.333C>T p.F111= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60812008; called by muse, mutect2, varscan2
- FCRL3 | c.939G>A p.Q313= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV100942942, COSV100943449; called by muse, mutect2, varscan2
- FCRL4 | c.921C>T p.V307= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV54863051; called by muse, mutect2, varscan2
- FKBP9 | c.1689G>A p.Q563= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99639112; called by muse, mutect2, varscan2
- FOXJ1 | c.441C>T p.I147= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV99486704; called by muse, mutect2, varscan2
- FYCO1 | c.2697C>T p.H899= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99945299; called by muse, mutect2, varscan2
- GATAD2A | c.1155C>T p.I385= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99389780; called by muse, mutect2, varscan2
- GC | c.138C>T p.V46= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2, varscan2
- GGN | c.306G>A p.G102= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99287356; called by muse, mutect2, varscan2
- GGPS1 | c.699C>T p.I233= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99270362; called by muse, mutect2, varscan2
- GGT1 | c.948C>T p.I316= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV50642206; called by muse, mutect2, varscan2
- GGT7 | c.282C>T p.S94= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs972812335, COSV100321802; called by muse, mutect2, varscan2
- GJA1 | c.1143G>A p.E381= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV99246866; called by muse, mutect2, varscan2
- GLTP | c.363C>T p.P121= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs148094807; called by muse, mutect2, varscan2
- GMPPA | c.1009C>T p.L337= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as COSV100354540; called by muse, mutect2, varscan2
- GPR139 | c.615C>T p.I205= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV58505858; called by muse, mutect2, varscan2
- GPR20 | c.483C>T p.C161= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100897278; called by muse, mutect2
- GRIK1 | c.1638A>G p.K546= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100516091; called by muse, mutect2, varscan2
- GRIN2A | c.558C>T p.F186= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs755062373, COSV58024125; called by muse, mutect2, varscan2
- GTF3C1 | c.1062C>T p.S354= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV100649077; called by muse, mutect2, varscan2
- HEATR4 | c.3004C>T p.L1002= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs1332019797, COSV100620223; called by muse, mutect2, varscan2
- HOXB1 | c.435G>A p.G145= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV99495353; called by muse, mutect2, varscan2
- HRH1 | c.843G>A p.K281= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs369093088; called by muse, mutect2, varscan2
- HYDIN | c.12042C>T p.I4014= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV101124958; called by muse, mutect2, varscan2
- IGHG2 | c.366C>T p.F122= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs753006113; called by muse, mutect2, varscan2
- IGSF9 | c.3099C>T p.F1033= (on ENST00000368094 / NM_001135050.2; = p.F1017= on NM_020789.4) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100230998; called by muse, mutect2, varscan2
- IKZF3 | c.958C>T p.L320= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV99499324; called by muse, mutect2, varscan2
- IL32 | c.549G>A p.L183= (on ENST00000396890 / NM_001308078.4; = p.L137= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs752150665, COSV50404420, COSV99145463; called by muse, mutect2, varscan2
- IL7R | c.372C>T p.T124= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV100285999, COSV57407753; called by muse, mutect2, varscan2
- IMPG1 | c.240C>T p.V80= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100886198; called by muse, mutect2, varscan2
- ING4 | c.702G>A p.R234= (on ENST00000396807 / NM_001127582.2; = p.R233= on NM_016162.4) | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV99975979, COSV99976060; called by muse, mutect2, varscan2
- IP6K2 | c.165C>T p.L55= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as COSV100151747; called by muse, mutect2, varscan2
- ITGA11 | c.84G>A p.R28= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59879813; called by muse, mutect2, varscan2
- KANK4 | c.117C>T p.F39= | Silent (SNP) | VAF 89/207 reads (43%) | catalogued as rs778541639, COSV100587161; called by muse, mutect2, varscan2
- KCNG4 | c.444C>T p.A148= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100376941; called by muse, mutect2, varscan2
- KCNK16 | c.900C>T p.F300= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV100949121; called by muse, mutect2
- KCNK5 | c.678C>T p.F226= | Silent (SNP) | VAF 70/238 reads (29%) | catalogued as rs1017757180, COSV100851769; called by muse, mutect2, varscan2
- KL | c.1845C>T p.I615= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV101199035; called by muse, mutect2, varscan2
- KMT2D | c.13713C>T p.A4571= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV99978505; called by muse, mutect2, varscan2
- KNG1 | c.1167A>G p.R389= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV99405263; called by muse, mutect2, varscan2
- LAMA1 | c.7851G>A p.T2617= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1432682156, COSV67531451; called by muse, mutect2, varscan2
- LINGO2 | c.1542C>T p.T514= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV100430284; called by muse, mutect2, varscan2
- LMO3 | c.358C>T p.L120= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs1307854873, COSV99662656; called by muse, mutect2, varscan2
- LRRC30 | c.288C>T p.I96= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs1326716559, COSV67301328; called by muse, mutect2, varscan2
- LRRC73 | c.747G>A p.Q249= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99446271; called by muse, mutect2, varscan2
- LRRC8C | c.1539C>T p.L513= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs796603827, COSV100968113; called by muse, mutect2, varscan2
- MAN1A2 | c.1587C>T p.I529= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs778406715, COSV62976659; called by muse, mutect2, varscan2
- MAP2K6 | c.75C>T p.T25= | Silent (SNP) | VAF 81/124 reads (65%) | catalogued as COSV100765058; called by muse, mutect2, varscan2
- MAPK15 | c.1011C>T p.S337= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100567739; called by muse, mutect2, varscan2
- MAST3 | c.3282C>T p.S1094= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1461582734, COSV53226466; called by muse, mutect2, varscan2
- MCM7 | c.1551C>T p.L517= | Silent (SNP) | VAF 47/191 reads (25%) | catalogued as rs149943121; called by muse, mutect2, varscan2
- MED13L | c.5220A>G p.Q1740= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99928090; called by muse, mutect2, varscan2
- MGAM | c.2523C>T p.I841= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs747370287, COSV101527409; called by muse, mutect2, varscan2
- MRGPRX1 | c.621G>A p.R207= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV100245895; called by muse, mutect2, varscan2
- MUC16 | c.24012C>T p.L8004= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1468574140, COSV101198674; called by muse, mutect2, varscan2
- MUC5B | c.10197C>A p.A3399= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101500093; called by muse, mutect2
- MUC5B | c.12285G>A p.R4095= | Silent (SNP) | VAF 78/288 reads (27%) | catalogued as COSV101500095; called by muse, mutect2, varscan2
- MYH3 | c.3114C>T p.S1038= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV99877866; called by muse, mutect2, varscan2
- NAA60 | c.513C>T p.L171= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100692738; called by muse, mutect2, varscan2
- NDST1 | c.1407C>T p.Y469= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99938681; called by muse, mutect2, varscan2
- NEB | c.8028G>A p.E2676= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV99416809; called by muse, mutect2, varscan2
- NLRP1 | c.3822A>T p.R1274= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99333259; called by muse, mutect2, varscan2
- NLRP5 | c.1251C>T p.L417= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV101173438; called by muse, mutect2, varscan2
- NOMO2 | c.1095C>T p.F365= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV57916153; called by mutect2, varscan2
- OAS3 | c.339C>T p.V113= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV99966129; called by muse, mutect2, varscan2
- OR11H1 | c.171G>A p.R57= | Silent (SNP) | VAF 45/300 reads (15%) | catalogued as rs772562238, COSV99421647; called by muse, varscan2
- OR1L4 | c.669C>T p.I223= | Silent (SNP) | VAF 65/499 reads (13%) | catalogued as rs140014211, COSV52341184; called by muse, mutect2, varscan2
- OR1M1 | c.702G>A p.R234= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV101447548; called by muse, mutect2, varscan2
- OR2T2 | c.249C>T p.L83= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as COSV100737590; called by muse, mutect2
- OR2T34 | c.531G>A p.R177= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV100170301, COSV60899697; called by muse, mutect2, varscan2
- OR2T35 | c.249C>T p.L83= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100442197; called by muse, mutect2, varscan2
- OR3A3 | c.36G>A p.G12= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99351302; called by muse, mutect2, varscan2
- OR4D9 | c.183C>T p.F61= | Silent (SNP) | VAF 75/287 reads (26%) | catalogued as rs1348014499, COSV61435526; called by muse, mutect2, varscan2
- OR4M1 | c.393C>T p.H131= | Silent (SNP) | VAF 62/250 reads (25%) | catalogued as COSV100270989; called by muse, varscan2
- OR4Q3 | c.336C>T p.F112= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100056830; called by muse, mutect2, varscan2
- OR52N4 | c.942G>A p.K314= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100421597; called by muse, mutect2, varscan2
- OR5P3 | c.879G>A p.R293= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100103042; called by muse, mutect2, varscan2
- OR6V1 | c.681C>T p.P227= | Silent (SNP) | VAF 80/252 reads (32%) | catalogued as COSV69236931, COSV69237469; called by muse, mutect2, varscan2
- OR8H2 | c.345C>T p.L115= | Silent (SNP) | VAF 120/412 reads (29%) | catalogued as COSV100542184; called by muse, mutect2, varscan2
- P4HB | c.1017C>T p.I339= | Silent (SNP) | VAF 104/172 reads (60%) | catalogued as COSV100515773; called by muse, mutect2, varscan2
- PARVB | c.252C>T p.P84= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100114591; called by muse, mutect2, varscan2
- PAXIP1 | c.2709C>T p.L903= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs1353023158, COSV101249237; called by muse, mutect2, varscan2
- PCDHA2 | c.48C>T p.L16= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs782681638, COSV65371650; called by muse, mutect2, varscan2
- PCDHB2 | c.123G>A p.T41= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs1563825576, COSV52036073; called by muse, mutect2, varscan2
- PDZRN4 | c.1818C>T p.L606= (on ENST00000402685 / NM_001164595.2; = p.L348= on NM_013377.4) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs773791840, COSV100113871, COSV54194642, COSV54210036; called by muse, mutect2, varscan2
- PGAM2 | c.531C>T p.A177= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs555158017, COSV51978949; called by muse, mutect2, varscan2
- PHC2 | c.1902G>A p.E634= (on ENST00000257118 / NM_198040.2; = p.E99= on NM_004427.4) | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as COSV99930785; called by muse, mutect2, varscan2
- PKP4 | c.678C>T p.I226= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV101080419; called by muse, mutect2, varscan2
- PLXNA4 | c.1323G>A p.K441= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100323026; called by muse, mutect2, varscan2
- PLXND1 | c.5694C>T p.A1898= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as rs774441360, COSV100139207; called by muse, mutect2, varscan2
- POLR1B | c.1449C>A p.T483= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as COSV99637303; called by muse, mutect2, varscan2
- POLR2A | c.4119C>T p.A1373= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs764110481; called by muse, mutect2, varscan2
- POTEE | c.2397G>A p.E799= | Silent (SNP) | VAF 77/273 reads (28%) | catalogued as COSV58228730; called by muse, mutect2, varscan2
- POU2F1 | c.1041G>A p.E347= (on ENST00000541643 / NM_001365848.1; = p.E370= on NM_002697.4) | Silent (SNP) | VAF 40/154 reads (26%) | catalogued as COSV99610612; called by muse, mutect2, varscan2
- POU4F2 | c.774G>A p.L258= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99850372; called by muse, mutect2, varscan2
- PPIP5K2 | c.993C>T p.S331= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV58607120; called by muse, mutect2, varscan2
- PRAMEF14 | c.840C>T p.F280= | Silent (SNP) | VAF 66/292 reads (23%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.207G>A p.L69= | Silent (SNP) | VAF 92/177 reads (52%) | catalogued as rs1051725354; called by muse, mutect2, varscan2
- PRKD1 | c.2565C>T p.I855= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs143388121; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1392C>T p.N464= (on ENST00000352766; = p.N385= on NM_181334.5) | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as rs1227730118, COSV100424040; called by muse, mutect2, varscan2
- PUS1 | c.1104C>T p.F368= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100435156; called by muse, mutect2, varscan2
- PXYLP1 | c.540G>A p.L180= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV99649278; called by muse, mutect2, varscan2
- RAD54L2 | c.1263G>A p.P421= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs750532396, COSV56580108; called by muse, mutect2, varscan2
- RAF1 | c.777C>T p.S259= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV99312091; called by muse, mutect2, varscan2
- RASGRP2 | c.1272G>A p.V424= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100818191; called by muse, mutect2, varscan2
- RFX5 | c.657C>T p.S219= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as rs745851232, COSV100923845; called by muse, mutect2, varscan2
- RING1 | c.1011G>A p.G337= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs753342089, COSV100761731; called by muse, mutect2, varscan2
- RNASE12 | c.150C>T p.I50= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV100250460; called by muse, mutect2, varscan2
- RNF214 | c.1257C>T p.I419= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as COSV100326540; called by muse, mutect2, varscan2
- RUFY4 | c.1677C>T p.C559= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs987626471, COSV100722967; called by mutect2, varscan2
- SALL1 | c.3225G>A p.V1075= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99171794; called by muse, mutect2, varscan2
- SCN1A | c.5841C>T p.I1947= (on ENST00000303395 / NM_001202435.3; = p.I1936= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100319612, COSV100320027; called by muse, mutect2, varscan2
- SCP2 | c.1059G>A p.K353= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs1333522318, COSV101026875; called by muse, mutect2, varscan2
- SELP | c.279G>A p.G93= | Silent (SNP) | VAF 80/243 reads (33%) | catalogued as COSV99739225; called by muse, mutect2, varscan2
- SFSWAP | c.186C>T p.P62= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs1012863166, COSV99905868; called by muse, mutect2, varscan2
- SHKBP1 | c.1011C>T p.L337= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV99398965; called by muse, mutect2, varscan2
- SHROOM4 | c.4116G>A p.L1372= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99173116; called by muse, mutect2, varscan2
- SLC12A7 | c.2688G>A p.Q896= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV99369464; called by muse, mutect2, varscan2
- SLC13A2 | c.915G>A p.Q305= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100120185; called by muse, mutect2, varscan2
- SLC6A11 | c.549C>T p.F183= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99594177; called by muse, mutect2, varscan2
- SLC7A6 | c.1242G>A p.K414= | Silent (SNP) | VAF 55/180 reads (31%) | catalogued as COSV99546455; called by muse, mutect2, varscan2
- SLIT3 | c.3471C>T p.L1157= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs142117627; called by muse, mutect2, varscan2
- SLX4 | c.4878C>T p.C1626= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as rs1213504120, COSV99567728; called by muse, mutect2, varscan2
- SPTA1 | c.4170C>T p.I1390= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as COSV100934523; called by muse, mutect2, varscan2
- SPTLC3 | c.1233C>T p.I411= | Silent (SNP) | VAF 62/193 reads (32%) | catalogued as COSV65464583; called by muse, mutect2, varscan2
- STAG3 | c.1875C>T p.F625= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100425714; called by muse, mutect2, varscan2
- SUMO1 | c.285G>A p.T95= | Silent (SNP) | VAF 105/409 reads (26%) | catalogued as rs760175264, COSV101108598; called by muse, mutect2, varscan2
- SYT2 | c.831C>T p.S277= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100937124; called by muse, mutect2, varscan2
- SYTL3 | c.1350G>A p.E450= (on ENST00000611299 / NM_001242394.1; = p.E382= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs564634611, COSV51915548; called by muse, mutect2, varscan2
- TBXAS1 | c.1230C>T p.F410= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV54946062; called by muse, mutect2, varscan2
- TECPR1 | c.1836C>T p.T612= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs377059632; called by muse, mutect2, varscan2
- THBS2 | c.3237G>A p.R1079= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100827699; called by muse, mutect2, varscan2
- THSD7B | c.588G>A p.G196= | Silent (SNP) | VAF 82/287 reads (29%) | catalogued as COSV99746016; called by muse, mutect2, varscan2
- TLE4 | c.834C>T p.G278= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as COSV99511432; called by muse, mutect2, varscan2
- TMC5 | c.1140G>A p.R380= (on ENST00000396229 / NM_001105248.1; = p.R134= on NM_024780.5) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs759329582, COSV54900836; called by muse, mutect2, varscan2
- TMEM43 | c.144C>T p.Y48= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99853913; called by muse, mutect2, varscan2
- TMEM63B | c.1569C>T p.I523= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV99441153; called by muse, mutect2, varscan2
- TPO | c.2709G>A p.G903= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV100220063; called by muse, mutect2, varscan2
- TRAPPC9 | c.1519C>T p.L507= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV101226907; called by muse, mutect2, varscan2
- TTC4 | c.237C>T p.A79= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100988385; called by muse, mutect2
- TTN | c.90102C>T p.I30034= (on ENST00000591111; = p.I22610= on NM_003319.4) | Silent (SNP) | VAF 65/223 reads (29%) | catalogued as COSV100599382; called by muse, mutect2, varscan2
- TTN | c.72846C>T p.I24282= (on ENST00000591111; = p.I16858= on NM_003319.4) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs780766847, COSV100599386; called by muse, mutect2, varscan2
- TTN | c.20130G>A p.G6710= (on ENST00000591111; = p.G5783= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs777605427, COSV59912298; called by muse, mutect2, varscan2
- TXNL1 | c.513C>T p.F171= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV54178342, COSV99469489; called by muse, mutect2, varscan2
- UBE2O | c.1071C>T p.F357= | Silent (SNP) | VAF 67/100 reads (67%) | catalogued as rs753050594, COSV100084253; called by muse, mutect2, varscan2
- UBE4B | c.3261C>T p.L1087= (on ENST00000343090 / NM_001105562.3; = p.L958= on NM_006048.5) | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs758182185, COSV53539749; called by muse, mutect2, varscan2
- UBN1 | c.3009G>T p.S1003= | Silent (SNP) | VAF 61/209 reads (29%) | catalogued as COSV99277618, COSV99278708; called by muse, mutect2, varscan2
- UMODL1 | c.117C>T p.H39= | Silent (SNP) | VAF 63/230 reads (27%) | catalogued as COSV101253071; called by muse, mutect2, varscan2
- UMODL1 | c.3039C>T p.P1013= (on ENST00000408910 / NM_001004416.2; = p.P1141= on NM_173568.3) | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs760800247, COSV68569560; called by muse, mutect2, varscan2
- VPS33A | c.1681C>T p.L561= | Silent (SNP) | VAF 63/184 reads (34%) | catalogued as COSV99931242; called by muse, mutect2, varscan2
- XIRP2 | c.6558G>A p.S2186= (on ENST00000628543; = p.S2361= on NM_152381.6) | Silent (SNP) | VAF 61/196 reads (31%) | catalogued as rs755408315, COSV54735296; called by muse, mutect2, varscan2
- XKR7 | c.1107C>T p.I369= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV101629239; called by muse, mutect2, varscan2
- XRCC6 | c.906C>T p.T302= | Silent (SNP) | VAF 71/320 reads (22%) | catalogued as rs1354699289, COSV100777797, COSV63158618; called by muse, mutect2, varscan2
- ZNF141 | c.930C>T p.P310= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV99549490; called by muse, mutect2, varscan2
- ZNF17 | c.891C>T p.T297= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as COSV100299948; called by muse, mutect2, varscan2
- ZNF197 | c.2271C>T p.T757= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs369322524; called by muse, mutect2, varscan2
- ZNF311 | c.297C>T p.N99= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as rs1397041305, COSV101014089; called by muse, mutect2, varscan2
- ZNF415 | c.159C>T p.I53= | Silent (SNP) | VAF 57/118 reads (48%) | catalogued as rs1432715348, COSV99701335; called by muse, mutect2, varscan2
- ZNF665 | c.654C>T p.I218= (on ENST00000600412; = p.I283= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/223 reads (18%) | catalogued as rs1339062872, COSV101128013; called by muse, mutect2, varscan2
- ZNF687 | c.735C>T p.A245= | Silent (SNP) | VAF 61/221 reads (28%) | catalogued as COSV99649391; called by muse, mutect2, varscan2
- AC024940.1 | n.2458G>A | RNA (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- ASPH | c.322+4743C>T | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100727431; called by muse, mutect2
- CD53 | c.-2G>A | 5'UTR (SNP) | VAF 31/73 reads (42%) | catalogued as rs746688487, COSV99602129; called by muse, mutect2, varscan2
- DZIP1L | c.-1C>T | 5'UTR (SNP) | VAF 37/110 reads (34%) | catalogued as COSV100551201; called by muse, mutect2, varscan2
- MASP1 | c.1303+5570G>A | Intron (SNP) | VAF 19/76 reads (25%) | catalogued as rs774753334, COSV99961958; called by muse, mutect2, varscan2
- MIR99A | n.26G>A | RNA (SNP) | VAF 19/48 reads (40%) | catalogued as rs745780413; called by muse, mutect2, varscan2
- RPL26P30 | n.650C>T | RNA (SNP) | VAF 65/250 reads (26%) | called by muse, mutect2, varscan2
- SNORD115-10 | n.35G>A | RNA (SNP) | VAF 168/679 reads (25%) | called by muse, mutect2, varscan2
- ST6GALNAC6 | c.*117C>T | 3'UTR (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99398384; called by muse, mutect2, varscan2
- TTN | c.10360+4546C>T | Intron (SNP) | VAF 55/158 reads (35%) | catalogued as rs558862374, COSV100589271; called by muse, mutect2, varscan2
- TTN | c.10303+2548C>T | Intron (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100599408; called by muse, mutect2, varscan2
